Somatic mutation profile of tumor specimen MP2PRT-PATBIW-TMP1-A (aliquot MP2PRT-PATBIW-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATBIW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,122 days).
Specimen MP2PRT-PATBIW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b538d04-46a7-4d6c-9708-a6ecc1fc0fa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBIW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBIW-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/052d72db-387e-48d1-a364-88076191e9d9

The open-access MAF lists 66 somatic variants for this specimen: 45 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 19, Intron 2, Nonsense Mutation 2, Splice Region 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 38/155 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.8362A>G p.I2788V | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.036); catalogued as rs1324514744; called by muse, mutect2, varscan2
- ARMS2 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 47/480 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV73307030; called by muse, mutect2
- CPAMD8 | c.3510C>T p.I1170= (on ENST00000651564; = p.I1123= on NM_015692.5) | Splice Region (SNP) | VAF 82/361 reads (23%) | catalogued as rs369181262; called by muse, mutect2, varscan2
- DNAH11 | c.3157C>G p.L1053V | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.754); catalogued as COSV60939877, COSV60941522, COSV60964341; called by muse, mutect2, varscan2
- DNAH11 | c.3464C>G p.S1155C | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1363132561; called by muse, mutect2, varscan2
- EHBP1 | c.1807G>A p.G603R | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as rs778582026; called by muse, mutect2, varscan2
- EHMT1 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 12/446 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100604275; called by muse, mutect2
- EPHA5 | c.469G>C p.E157Q | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56647704; called by muse, mutect2, varscan2
- EXO5 | c.1062G>C p.W354C | Missense Mutation (SNP) | VAF 160/376 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56416783; called by muse, mutect2, varscan2
- FREM2 | c.6538C>T p.R2180C | Missense Mutation (SNP) | VAF 159/339 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201190773, COSV54831178; called by muse, mutect2, varscan2
- GDAP1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 122/312 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs771810975; ClinVar: uncertain significance; called by muse, varscan2
- GRIK1 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV58730945, COSV58732839; called by muse, mutect2, varscan2
- HRNR | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 248/532 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs551059466, COSV100912675; called by muse, mutect2, varscan2
- IFI16 | c.664G>C p.E222Q | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV99857699; called by mutect2, varscan2
- LPO | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs764179599; called by muse, mutect2, varscan2
- PLEKHA6 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 57/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs752795887; called by muse, mutect2, varscan2
- SIPA1L1 | c.2837C>G p.S946* | Nonsense Mutation (SNP) | VAF 42/183 reads (23%) | catalogued as rs1199267850, COSV100666183; called by muse, mutect2, varscan2
- THBS4 | c.1676G>C p.G559A | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.574); catalogued as COSV100644468; called by muse, mutect2, varscan2
- TLNRD1 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 108/578 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs747927954, COSV51256815, COSV51257583; called by muse, mutect2, varscan2
- ZNF808 | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.582); catalogued as rs1329043969; called by muse, mutect2, varscan2
- ABCC8 | c.825G>C p.R275= | Splice Region (SNP) | VAF 44/279 reads (16%) | called by muse, mutect2, varscan2
- ACOT13 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP10 | c.2146C>G p.P716A | Missense Mutation (SNP) | VAF 82/445 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- BIRC6 | c.9926C>T p.S3309F | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by mutect2, varscan2
- C1GALT1 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- C2orf16 | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CELF4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 60/441 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CFAP65 | c.198G>A p.M66I (on ENST00000341552 / NM_194302.4; = p.M1? on NM_152389.4) | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHPF2 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- CST1 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 200/495 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- DNAH6 | c.6691A>T p.S2231C | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- EGR4 | c.85G>C p.G29R | Missense Mutation (SNP) | VAF 20/662 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.605); called by muse, mutect2
- GSKIP | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HOOK3 | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); called by muse, mutect2
- IGKV2-24 | chr2:89176326 TGA>GGGAGG | Missense Mutation (INS) | VAF 74/93 reads (80%) | called by pindel, varscan2*
- PLBD1 | c.1258C>G p.Q420E | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.6817C>T p.Q2273* | Nonsense Mutation (SNP) | VAF 21/225 reads (9%) | called by muse, mutect2, varscan2
- RAB18 | c.103C>G p.P35A | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RNF17 | c.3102-1G>C p.X1034_splice | Splice Site (SNP) | VAF 51/230 reads (22%) | called by muse, mutect2, varscan2
- RTL6 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 19/578 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2
- SDR39U1 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 23/538 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- SLC9C2 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2
- STIM1 | c.2036_2037insCAGACCAC p.K680Rfs*71 | Frame Shift Ins (INS) | VAF 34/302 reads (11%) | called by mutect2, pindel
- ZNF638 | c.5643G>A p.M1881I | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADNP2 | c.2700C>T p.I900= | Silent (SNP) | VAF 45/408 reads (11%) | called by muse, mutect2, varscan2
- ANAPC2 | c.2457G>A p.K819= | Silent (SNP) | VAF 49/386 reads (13%) | catalogued as rs1259734935; called by muse, varscan2
- ANAPC2 | c.1995G>T p.V665= | Silent (SNP) | VAF 35/307 reads (11%) | called by muse, mutect2, varscan2
- ATG7 | c.2053C>T p.L685= | Silent (SNP) | VAF 27/234 reads (12%) | called by muse, mutect2, varscan2
- CCDC144A | c.48G>A p.P16= | Silent (SNP) | VAF 70/388 reads (18%) | catalogued as COSV61403591; called by muse, varscan2
- CNTRL | c.456C>T p.L152= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs776981451; called by muse, mutect2, varscan2
- CWF19L2 | c.510C>G p.L170= | Silent (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- DNAH5 | c.4713C>G p.L1571= | Silent (SNP) | VAF 45/356 reads (13%) | called by muse, mutect2, varscan2
- ITGA11 | c.2097G>A p.E699= | Silent (SNP) | VAF 75/442 reads (17%) | called by muse, mutect2, varscan2
- MUC15 | c.666C>G p.L222= | Silent (SNP) | VAF 15/166 reads (9%) | catalogued as COSV55553242; called by muse, mutect2
- NRCAM | c.1707G>A p.V569= (on ENST00000379028 / NM_001371124.1; = p.V563= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 88/448 reads (20%) | called by muse, mutect2, varscan2
- PCDHA9 | c.40C>T p.L14= | Silent (SNP) | VAF 54/336 reads (16%) | called by muse, mutect2, varscan2
- PIK3C2B | c.1512G>A p.L504= | Silent (SNP) | VAF 141/315 reads (45%) | called by muse, mutect2, varscan2
- PLAT | c.846G>A p.K282= | Silent (SNP) | VAF 65/375 reads (17%) | catalogued as COSV104373121; called by muse, mutect2, varscan2
- PPM1J | c.159G>C p.G53= | Silent (SNP) | VAF 92/788 reads (12%) | called by muse, mutect2, varscan2
- PTH2R | c.1203C>T p.F401= | Silent (SNP) | VAF 35/291 reads (12%) | catalogued as rs753457723; called by muse, mutect2, varscan2
- SPATA32 | c.576C>T p.L192= | Silent (SNP) | VAF 63/453 reads (14%) | catalogued as COSV59303764; called by muse, mutect2, varscan2
- TAF1L | c.1620C>G p.T540= | Silent (SNP) | VAF 58/450 reads (13%) | catalogued as COSV54271855; called by muse, mutect2, varscan2
- ZFPL1 | c.900C>G p.L300= | Silent (SNP) | VAF 69/619 reads (11%) | called by muse, mutect2, varscan2
- FOXP1 | c.181-17952C>T | Intron (SNP) | VAF 56/593 reads (9%) | catalogued as rs776051503, COSV100562173; ClinVar: uncertain significance; called by muse, mutect2
- KCNQ1 | c.1393+24314C>G | Intron (SNP) | VAF 30/334 reads (9%) | called by muse, mutect2
